Gene-level copy-number profile of tumor specimen TCGA-25-1635-01A from TCGA case TCGA-25-1635, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 71.7 years (26,200 days).
Specimen TCGA-25-1635-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.ad7b6bfa-58a2-47ef-8dea-981ccd71b872.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-25-1635-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0f8caaf2-3ac9-4a99-bd4d-d18b536f764e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,318; copy number 2: 27,270; copy number 3: 22,168; copy number 4: 5,856; copy number 5: 551; copy number 6: 939; copy number 7: 195; copy number 8: 6; copy number 9: 43; copy number 10: 56; copy number 11: 108; copy number 12: 2; copy number 13: 11; copy number 15: 28; copy number 17: 52; copy number 19: 70; copy number 23: 114; copy number 26: 27.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-25-1635-01): tumor purity 0.69, ploidy 2.72, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,202 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,096–11,919,688, 319 genes, copy number 5 (broad region; genes not listed).
- chr4:24,517,441–37,241,991, 108 genes, copy number 5 (broad region; genes not listed).
- chr4:37,891,084–43,234,956, 110 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr4:57,841,721–58,118,070, 3 genes, copy number 5: AC104790.1, SRIP1, AC096725.1.
- chr4:70,902,326–77,150,437, 112 genes, copy number 11–26 (within-gene range 3–26) (broad region; genes not listed).
- chr8:96,239,398–145,066,685, 773 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr11:76,381,303–79,612,300, 70 genes, copy number 7–11 (broad region; genes not listed).
- chr12:19,404,045–19,720,801, 1 gene, copy number 6 (within-gene range 4–6): AEBP2.
- chr12:19,445,949–34,249,958, 275 genes, copy number 6–17 (broad region; genes not listed).
- chr19:20,674,923–20,983,210, 11 genes, copy number 5: AC010329.5, AC010329.2, AC010329.1, VN1R79P, ZNF66, BNIP3P24, AC008739.2, ZNF85, AC008739.6, KRT18P40, AC008739.1.
- chr19:27,638,483–32,072,113, 82 genes, copy number 7–11 (within-gene range 2–11) (broad region; genes not listed).
- chr19:33,795,933–34,066,283, 6 genes, copy number 7 (within-gene range 4–7): KCTD15, AC008556.1, RN7SL150P, AC016587.1, RPS4XP23, RPS4XP20.
- chr19:35,090,930–41,062,444, 332 genes, copy number 7–23 (within-gene range 4–23) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,318. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
